Somatic mutation profile of tumor specimen 0DQJIW from CCDI case PBCFDV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.7 years (2,072 days).
Specimen 0DQJIW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fcfb1929-4b24-4334-ace4-e7fcbf22ca24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQJIK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5970c3ce-7bdd-42f6-83b7-df074b9eebc6

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DLG3 | c.2081C>T p.A694V (on ENST00000374360 / NM_021120.4; = p.A389V on NM_020730.3) | Missense Mutation (SNP) | VAF 57/341 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52079708; called by muse, mutect2, varscan2
- ST8SIA2 | c.929T>C p.I310T | Missense Mutation (SNP) | VAF 23/446 reads (5%) | PolyPhen probably damaging (0.998); catalogued as COSV51569002; called by muse, mutect2
